Somatic mutation profile of tumor specimen TCGA-33-4589-01A (aliquot TCGA-33-4589-01A-01D-1441-08) from TCGA case TCGA-33-4589, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.3 years (22,754 days).
Specimen TCGA-33-4589-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0702a5d-c349-45e2-9973-e8dfc3d68c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4589-11A (Solid Tissue Normal), aliquot TCGA-33-4589-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f66d352-6d4b-4b62-8782-329c3a5ae923

The open-access MAF lists 118 somatic variants for this specimen: 88 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 28, Nonsense Mutation 8, Frame Shift Del 4, Splice Site 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, varscan2
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, varscan2
- NFE2L2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as COSV100563770; called by muse, mutect2, varscan2
- ACAP1 | c.1811G>A p.G604D | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs762488840, COSV50134921; called by muse, mutect2, varscan2
- ACOT2 | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99468739, COSV99469073; called by muse, mutect2, varscan2
- ADAMTS12 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs369766198; called by muse, mutect2, varscan2
- AKAP5 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100277829; called by muse, mutect2, varscan2
- B3GNT8 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as COSV99524394; called by muse, mutect2, varscan2
- BMP15 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs782079720, COSV53139772; called by muse, mutect2
- BRIX1 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100384447; called by muse, mutect2, varscan2
- C8orf34 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100444132; called by muse, mutect2
- CAMTA2 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV52776372; called by muse, mutect2
- CERKL | c.1492C>T p.H498Y (on ENST00000339098 / NM_001030311.2; = p.H472Y on NM_201548.5) | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV59207568; called by muse, mutect2, varscan2
- CERS4 | c.612G>A p.K204= | Splice Region (SNP) | VAF 18/120 reads (15%) | catalogued as rs376322955; called by muse, mutect2, varscan2
- CLIC5 | c.1216C>T p.R406C (on ENST00000185206 / NM_001370649.1; = p.R247C on NM_016929.5) | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202022202, COSV51759804; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.3337-1G>T p.X1113_splice | Splice Site (SNP) | VAF 12/151 reads (8%) | catalogued as CS114435, COSV99241977; called by muse, mutect2
- CREBBP | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99268435; called by muse, mutect2, varscan2
- CYLC2 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.187); catalogued as COSV100872348; called by muse, mutect2, varscan2
- CYP4F8 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as rs756196035, COSV100358002, COSV57853075; called by muse, mutect2, varscan2
- DCAF5 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV100432168; called by muse, mutect2, varscan2
- DCK | c.653A>T p.H218L | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99709089; called by muse, mutect2
- DDX49 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1042865795, COSV99650870; called by muse, mutect2
- DGCR2 | c.862A>T p.K288* | Nonsense Mutation (SNP) | VAF 136/605 reads (22%) | catalogued as COSV99593210; called by muse, mutect2, varscan2
- DGKH | c.3019T>G p.C1007G | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as COSV99818222; called by muse, mutect2
- DNAH11 | c.4489G>C p.E1497Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100176731; called by muse, varscan2
- DNMT3L | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | catalogued as COSV99533151; called by muse, mutect2, varscan2
- DOK2 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs745897950, COSV52390764; called by muse, mutect2, varscan2
- DST | c.7303G>A p.E2435K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV99750569; called by muse, mutect2
- FAM155A | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs763303628, COSV65592258; called by muse, mutect2
- FAT1 | c.7540del p.V2514* | Frame Shift Del (DEL) | VAF 57/307 reads (19%) | catalogued as COSV71675789; called by mutect2, pindel, varscan2
- GCC1 | c.584A>C p.Q195P | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99133559; called by muse, mutect2, varscan2
- H2BC18 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV58944336; called by muse, mutect2, varscan2
- IARS2 | c.1985G>C p.G662A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100228059, COSV100228714; called by muse, mutect2, varscan2
- ICE2 | c.2590C>G p.H864D | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99831247; called by muse, mutect2, varscan2
- IFIH1 | c.2101C>G p.L701V | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718351; called by muse, mutect2
- JAK2 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.505); catalogued as COSV101070339, COSV67587704; called by muse, mutect2, varscan2
- LGSN | c.1076T>C p.M359T | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as rs1057109766, COSV101040219, COSV65728939; called by muse, mutect2, varscan2
- LIN54 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100464207; called by muse, mutect2, varscan2
- LRP2 | c.4988G>A p.R1663H | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200766881, COSV55541498; called by muse, mutect2
- MAST1 | c.2340G>C p.E780D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV99262220; called by muse, mutect2, varscan2
- MRGPRF | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV100307774; called by muse, mutect2
- MTF2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as rs1166723863, COSV100940042; called by muse, mutect2, varscan2
- MTF2 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 17/166 reads (10%) | catalogued as COSV100940043; called by muse, mutect2, varscan2
- MYEF2 | c.444C>G p.F148L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99981137; called by muse, mutect2
- NFAT5 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100590396; called by muse, mutect2, varscan2
- NRDC | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.33); catalogued as COSV100703034; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.352G>A p.E118K (on ENST00000374531 / NM_001037293.2; = p.E116K on NM_007203.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV100092496; called by muse, mutect2, varscan2
- PHLPP2 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 44/161 reads (27%) | catalogued as rs575871196, COSV100673465; called by muse, mutect2, varscan2
- PLCB2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs779992442, COSV53033806; called by muse, mutect2, varscan2
- PLEC | c.1682G>A p.R561Q (on ENST00000322810 / NM_201380.4; = p.R451Q on NM_000445.5) | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs199965040, COSV100510138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG4B | c.3448T>G p.C1150G (on ENST00000283426; = p.C1506G on NM_052909.5) | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.062); catalogued as COSV99359730; called by muse, mutect2, varscan2
- PLXNA4 | c.2558G>T p.S853I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV100322254; called by muse, mutect2, varscan2
- PRICKLE2 | c.2364C>G p.F788L (on ENST00000295902; = p.F732L on NM_198859.4) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV55769813, COSV55773055; called by muse, mutect2, varscan2
- PRKCE | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV60316951, COSV60330112; called by muse, mutect2, varscan2
- RELN | c.6365C>T p.A2122V | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100632224; called by muse, mutect2, varscan2
- RFNG | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100135817; called by muse, mutect2
- RFX5 | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as COSV100923814; called by muse, mutect2, varscan2
- RIPOR1 | c.1034T>A p.F345Y (on ENST00000379312 / NM_001193522.2; = p.F341Y on NM_024519.4) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99242463; called by muse, mutect2, varscan2
- RXRB | c.1559C>G p.T520S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); catalogued as COSV100553378; called by muse, mutect2
- SEMA3C | c.593T>G p.I198S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99542292; called by muse, mutect2, varscan2
- SERAC1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 31/135 reads (23%) | catalogued as rs780182065, COSV65597875; called by muse, mutect2, varscan2
- SESTD1 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV101468020; called by muse, mutect2, varscan2
- SH2D2A | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 35/294 reads (12%) | catalogued as rs143525606, COSV63885056; called by muse, mutect2, varscan2
- SLC25A14 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV99502276; called by muse, mutect2, varscan2
- SLC25A24 | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV51445812; called by muse, mutect2, varscan2
- SPPL2A | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99961344; called by muse, mutect2, varscan2
- SYNDIG1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs369837050; called by muse, mutect2, varscan2
- TAS2R7 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99553539; called by muse, mutect2
- TCHH | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100914888; called by muse, mutect2, varscan2
- TNKS | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1455139918, COSV100126036; called by muse, mutect2, varscan2
- TTI1 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV100989558; called by muse, mutect2
- UBE4B | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV99475597; called by muse, mutect2, varscan2
- UGGT2 | c.3134C>T p.S1045L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV100948433; called by muse, mutect2
- VRTN | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV99832098; called by muse, mutect2, varscan2
- WWTR1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100640781, COSV62291677; called by muse, mutect2, varscan2
- ZBTB22 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV99801367; called by muse, varscan2
- ZBTB22 | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV99801369; called by muse, varscan2
- ZNF182 | c.1422G>A p.M474I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs782204454, COSV100526866, COSV59356988; called by muse, mutect2, varscan2
- ZNF37A | c.1476G>C p.Q492H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100697254; called by muse, mutect2
- ZNF621 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100182589; called by muse, mutect2, varscan2
- ZNF692 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV100133709; called by muse, mutect2, varscan2
- AC245033.1 | c.1574A>C p.E525A | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- BAG1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBGCP5 | c.2831G>A p.R944K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- UTP20 | c.7466_7469del p.L2489Sfs*27 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- WDR24 | c.1887_1920del p.L630Qfs*87 (on ENST00000248142; = p.L500Qfs*87 on NM_032259.4) | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | called by mutect2, pindel
- ZC3HAV1 | c.1328_1332del p.R443Ifs*7 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | called by mutect2, pindel, varscan2
- CD44 | c.1959C>T p.I653= | Silent (SNP) | VAF 46/207 reads (22%) | catalogued as COSV99555391; called by muse, mutect2, varscan2
- DUSP29 | c.531G>T p.V177= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100633229; called by muse, mutect2, varscan2
- ECM1 | c.636C>T p.F212= | Silent (SNP) | VAF 55/203 reads (27%) | catalogued as COSV100681604; called by muse, mutect2, varscan2
- EXOSC10 | c.1308C>T p.Y436= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as rs765699100, COSV58665230; called by muse, mutect2, varscan2
- HELQ | c.1812A>G p.E604= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs1474865547, COSV99787377; called by muse, mutect2
- IGHA1 | c.198G>A p.T66= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs767116000; called by muse, mutect2, varscan2
- KCNMB4 | c.210C>T p.F70= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as COSV99252804; called by muse, mutect2, varscan2
- LRRTM3 | c.1410G>A p.K470= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV100791457; called by muse, mutect2, varscan2
- MKI67 | c.5046G>A p.Q1682= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV100896116; called by muse, mutect2, varscan2
- NAIF1 | c.165C>T p.V55= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs1270811885, COSV100895707; called by muse, mutect2, varscan2
- OR2T1 | c.144C>T p.I48= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV100822247, COSV63542330; called by muse, mutect2, varscan2
- OSBPL10 | c.834G>A p.L278= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV101158827; called by muse, mutect2, varscan2
- PCDHAC2 | c.495G>A p.A165= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99144214; called by muse, mutect2, varscan2
- PDCD10 | c.138C>T p.A46= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs369848466, CD135553, COSV67102383; called by muse, mutect2, varscan2
- PDS5A | c.3693C>T p.I1231= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100337143; called by muse, mutect2, varscan2
- PLCH2 | c.1014C>T p.T338= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99615460; called by muse, mutect2, varscan2
- PLK3 | c.414C>T p.F138= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100220997; called by muse, mutect2, varscan2
- PNPLA6 | c.3480G>A p.G1160= (on ENST00000414982 / NM_001166111.2; = p.G1112= on NM_006702.5) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs367675784, COSV55386170, COSV99653051; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PRDM13 | c.1998G>T p.P666= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100980430; called by muse, mutect2, varscan2
- SLC38A2 | c.1119C>G p.L373= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV99873702; called by muse, mutect2, varscan2
- SLC3A1 | c.303C>T p.I101= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs752281627, COSV53222489, COSV99576786; ClinVar: uncertain significance; called by muse, varscan2
- TRPA1 | c.870G>A p.L290= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as COSV100083037; called by muse, mutect2, varscan2
- TTC30A | c.1026C>T p.V342= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as COSV100826127; called by muse, mutect2
- UBA52 | c.336G>A p.K112= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV101471115; called by muse, mutect2, varscan2
- VWA5A | c.1470C>T p.V490= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV100827698; called by muse, mutect2, varscan2
- ZBTB20 | c.1053C>T p.N351= (on ENST00000474710 / NM_001164342.2; = p.N278= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV61865958; called by muse, mutect2, varscan2
- ZBTB22 | c.1743C>G p.P581= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99801364; called by muse, mutect2, varscan2
- ZMYM3 | c.1407C>G p.L469= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481-1911G>C | Intron (SNP) | VAF 15/106 reads (14%) | catalogued as COSV101125150; called by muse, mutect2
- VPS28 | c.549-21T>G | Intron (SNP) | VAF 18/159 reads (11%) | catalogued as COSV99465363; called by muse, mutect2, varscan2
